Somatic mutation profile of tumor specimen TCGA-AX-A1CE-01A (aliquot TCGA-AX-A1CE-01A-11D-A135-09) from TCGA case TCGA-AX-A1CE, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 60.1 years (21,969 days).
Specimen TCGA-AX-A1CE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8a317e3-64f6-47bc-9419-f81f8901363f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A1CE-10A (Blood Derived Normal), aliquot TCGA-AX-A1CE-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6f87d7a-0a94-4b6f-a435-0025c81b2d76

The open-access MAF lists 13,539 somatic variants for this specimen: 10,125 protein-altering or splice-affecting, 3,111 silent, 303 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8,970, Silent 3,111, Nonsense Mutation 626, Splice Site 170, Frame Shift Ins 153, Intron 133, Frame Shift Del 116, Splice Region 84, RNA 74, 3'UTR 41, 5'Flank 19, 3'Flank 19.

Variants (750 of 13,539; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1778C>T p.T593M | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs571555115, CM1313638, COSV55932538; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.3088C>T p.R1030* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as rs72653705, CM014487, COSV99228224; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTA2 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.947); catalogued as rs121434526, CM075972; ClinVar: pathogenic; called by mutect2, varscan2
- ACTC1 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs121912673, CM980030, COSV51757858; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADNP | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 34/74 reads (46%) | catalogued as rs1057518991, COSV62426779; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKRD11 | c.3309dup p.D1104Rfs*2 | Frame Shift Ins (INS) | VAF 28/61 reads (46%) | catalogued as rs772267579; ClinVar: pathogenic; called by mutect2, varscan2
- ATM | c.8545C>T p.R2849* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as rs587778080, CM990221, COSV53771567; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ATP7A | c.3802-1G>T p.X1268_splice | Splice Site (SNP) | VAF 27/62 reads (44%) | catalogued as rs398123135; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP7B | c.2827G>A p.G943S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28942076, CM950115, CM994112, COSV54442282; ClinVar: pathogenic; called by muse, varscan2
- BBS12 | c.1502C>T p.T501M | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138011813, CM070031; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.9097dup p.T3033Nfs*11 | Frame Shift Ins (INS) | VAF 37/83 reads (45%) | catalogued as rs397507419; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- BTK | c.215dup p.N72Kfs*13 | Frame Shift Ins (INS) | VAF 33/62 reads (53%) | catalogued as rs886041148; ClinVar: pathogenic; called by mutect2, varscan2
- CA1 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121909578, CM910066; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CIC | c.4543C>T p.R1515C | Missense Mutation (SNP) | VAF 13/27 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50560816, COSV50584645; called by muse, mutect2
- CLCN5 | c.2152C>T p.R718* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as rs797044814, CM033762, COSV56585339; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.1587+1G>A p.X529_splice | Splice Site (SNP) | VAF 26/78 reads (33%) | catalogued as rs104886313, CD961914, CS991352; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.3053G>A p.G1018D | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs1569498896, CM145030; ClinVar: pathogenic; called by muse, mutect2
- CRB1 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs62635654, CM992151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CUL4B | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 33/70 reads (47%) | catalogued as rs1569390220; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CWC27 | c.1002dup p.V335Sfs*13 | Frame Shift Ins (INS) | VAF 20/47 reads (43%) | catalogued as rs752159903; ClinVar: pathogenic; called by mutect2, varscan2
- DYRK1A | c.452dup p.N151Kfs*12 | Frame Shift Ins (INS) | VAF 19/47 reads (40%) | catalogued as rs797044523; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DYRK1A | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as rs724159949, CM1413207, COSV58294256; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ECHS1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs864309656, CM1510396, COSV63907009; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 27/64 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57246789; called by muse, mutect2, varscan2
- ERCC6 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 48/122 reads (39%) | catalogued as rs771781694, CM144884; ClinVar: likely pathogenic; called by muse, varscan2
- F8 | c.6956C>T p.P2319L | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852472, CM080273, CM1314829, CM910151, COSV100371734, COSV57705047; ClinVar: pathogenic; called by muse, varscan2
- FANCM | c.3148G>T p.E1050* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as rs1566764032; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGD4 | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 23/51 reads (45%) | catalogued as rs118203974, CM090824; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FOXP3 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as rs1057517736, CM1510215; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNPTAB | c.3335+1G>A p.X1112_splice | Splice Site (SNP) | VAF 76/212 reads (36%) | catalogued as rs34940801, CS054195; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GPSM2 | c.1492C>T p.R498* | Nonsense Mutation (SNP) | VAF 30/76 reads (39%) | catalogued as rs370907055, CM129500; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- IL17RA | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 32/86 reads (37%) | catalogued as rs778624945; ClinVar: pathogenic; called by muse, varscan2
- JAG1 | c.2230C>T p.R744* | Nonsense Mutation (SNP) | VAF 16/35 reads (46%) | catalogued as rs863223655, CD157115, CM981101, COSV54756275; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KARS1 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1415687857, COSV56691858; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KCNH2 | c.453del p.T152Pfs*14 | Frame Shift Del (DEL) | VAF 11/25 reads (44%) | catalogued as rs761863251, CD001499; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KCNT1 | c.2725C>T p.R909C (on ENST00000488444; = p.R928C on NM_020822.3) | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs397515405, CM129817, COSV53700743; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIAA0586 | c.-8dup | 5'UTR (INS) | VAF 42/91 reads (46%) | catalogued as rs745949846; ClinVar: pathogenic; called by mutect2, varscan2
- KRT14 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs58330629, CM034738, CM100400, CM910247; ClinVar: pathogenic; called by muse, mutect2
- KRT5 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs61297109, CM045867, CM103083, CM930459, COSV52860636; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- LIFR | c.1789C>T p.R597* | Nonsense Mutation (SNP) | VAF 52/140 reads (37%) | catalogued as rs121912501, CM040447, COSV54684100; ClinVar: pathogenic; called by muse, varscan2
- LIPT1 | c.79dup p.T27Nfs*14 | Frame Shift Ins (INS) | VAF 13/35 reads (37%) | catalogued as rs757713207; ClinVar: likely pathogenic; called by mutect2, varscan2
- LZTR1 | c.2264G>A p.R755Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs762834512, COSV53145154; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MECP2 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs61751443, CM000752, CM076285, CM106875; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MED12 | c.4831C>T p.R1611C | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs727503868, COSV100375342; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.741dup p.R248Tfs*8 | Frame Shift Ins (INS) | VAF 16/20 reads (80%) | catalogued as rs267608041; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707dup | Intron (INS) | VAF 17/46 reads (37%) | catalogued as rs747392139; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NF1 | c.4084C>T p.R1362* | Nonsense Mutation (SNP) | VAF 28/55 reads (51%) | catalogued as rs137854560, CM971046, COSV62191433, COSV62213078; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PC | c.3514G>A p.D1172N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs568925019; ClinVar: likely pathogenic; called by muse, varscan2
- PDK3 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as rs397515323, CM132388, COSV64792933; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PEX2 | c.310dup p.I104Nfs*19 | Frame Shift Ins (INS) | VAF 15/43 reads (35%) | catalogued as rs1235008965; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 27/72 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1049A>G p.D350G | Missense Mutation (SNP) | VAF 24/59 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs1553821144, COSV55877939, COSV55937337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 68/169 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554898129, CM110132, COSV64288974, COSV64292774, COSV64296979; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RRAS2 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs782457908, COSV56329532; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RSPO2 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758888137, COSV52641662; ClinVar: pathogenic; called by mutect2, varscan2
- SCN1A | c.2624C>T p.T875M (on ENST00000303395 / NM_001202435.3; = p.T864M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs121918623, CM000569, CM096132, COSV57669847; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- SGMS2 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as rs1560667389; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SIN3A | c.3310C>T p.R1104* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as rs879255621, COSV64581642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC26A2 | c.931T>C p.C311R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs377432261; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3127C>T p.R1043W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770014321, CM1310763, COSV60785646; ClinVar: likely pathogenic; called by muse, varscan2
- TRNT1 | c.1252dup p.S418Kfs*9 | Frame Shift Ins (INS) | VAF 6/25 reads (24%) | catalogued as rs876661298; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- VPS13A | c.9109C>T p.R3037* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as rs199807227, CM011922; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VPS13B | c.5737dup p.I1913Nfs*7 | Frame Shift Ins (INS) | VAF 34/78 reads (44%) | catalogued as rs386834096; ClinVar: likely pathogenic; called by mutect2, varscan2
- WEE2 | c.1477dup p.T493Nfs*39 | Frame Shift Ins (INS) | VAF 10/35 reads (29%) | catalogued as rs1554416415; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A2ML1 | c.3194G>T p.W1065L | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs748512560, COSV100228558; called by muse, mutect2, varscan2
- AAAS | c.1466C>T p.A489V | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as rs1265211389; called by muse, mutect2, varscan2
- AACS | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as rs746208598; called by muse, mutect2, varscan2
- AADAC | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as rs760075146; called by muse, mutect2, varscan2
- AADACL2 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 34/80 reads (43%) | catalogued as rs201287466, COSV62929985; called by muse, mutect2, varscan2
- AADACL3 | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs774957906; called by muse, mutect2, varscan2
- AARS2 | c.2873G>A p.R958Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs755585135, COSV55113496; called by muse, varscan2
- AASDHPPT | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); catalogued as rs868311667, COSV53789083; called by muse, mutect2, varscan2
- AASDHPPT | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs138269559; called by muse, mutect2, varscan2
- AASDHPPT | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1486827282; called by muse, mutect2, varscan2
- AASS | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs772963588; called by muse, mutect2, varscan2
- AASS | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs377136248; called by muse, mutect2, varscan2
- ABAT | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); catalogued as rs778229930, COSV51622239; called by muse, mutect2, varscan2
- ABCA12 | c.3694G>A p.G1232S (on ENST00000272895 / NM_173076.3; = p.G914S on NM_015657.3) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55963198; called by muse, mutect2, varscan2
- ABCA12 | c.2971A>G p.T991A (on ENST00000272895 / NM_173076.3; = p.T673A on NM_015657.3) | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.634); catalogued as rs1306652255; called by muse, mutect2, varscan2
- ABCA13 | c.8468T>C p.I2823T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1322751537; called by muse, mutect2, varscan2
- ABCA3 | c.3694C>T p.R1232C | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as rs1386770293, COSV57049403; called by muse, mutect2, varscan2
- ABCA3 | c.2140C>T p.R714C | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867072001; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB10 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752270393; called by muse, mutect2, varscan2
- ABCB11 | c.606C>A p.F202L | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99792914; called by muse, mutect2, varscan2
- ABCB11 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as rs776561679; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB4 | c.2858C>T p.A953V | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as CM055899; called by muse, mutect2, varscan2
- ABCB5 | c.2069C>A p.P690H (on ENST00000404938 / NM_001163941.2; = p.P245H on NM_178559.6) | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs749773246, COSV51722443; called by muse, mutect2, varscan2
- ABCB8 | c.902C>T p.A301V (on ENST00000297504 / NM_001282291.2; = p.A284V on NM_007188.5) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV52502443; called by muse, mutect2
- ABCB8 | c.1405C>T p.R469C (on ENST00000297504 / NM_001282291.2; = p.R452C on NM_007188.5) | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.19); PolyPhen benign (0.276); catalogued as rs1242097667; called by muse, mutect2, varscan2
- ABCC1 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV60694395; called by muse, mutect2, varscan2
- ABCC1 | c.4153C>T p.R1385* | Nonsense Mutation (SNP) | VAF 36/85 reads (42%) | catalogued as rs1479476888, COSV60681342; called by muse, mutect2, varscan2
- ABCC10 | c.3005G>A p.R1002H (on ENST00000372530 / NM_001198934.2; = p.R974H on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs759254534; called by muse, varscan2
- ABCC3 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs781282162; called by muse, mutect2, varscan2
- ABCC3 | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as rs374279400; called by muse, mutect2, varscan2
- ABCC4 | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as rs1435109800, COSV100972189, COSV65311125; called by muse, mutect2, varscan2
- ABCC9 | c.3605C>T p.T1202M | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.782); catalogued as CM140385, COSV53978242; called by muse, mutect2, varscan2
- ABCD1 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs782611445; called by muse, mutect2, varscan2
- ABCD3 | c.262C>T p.L88F | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as rs541543507; called by muse, mutect2, varscan2
- ABCF2 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99734677; called by muse, mutect2, varscan2
- ABCF2 | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs1253891179; called by muse, mutect2, varscan2
- ABCG1 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.24); PolyPhen benign (0.11); catalogued as rs774196934; called by muse, varscan2
- ABHD10 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs779860005, COSV56325045; called by muse, mutect2, varscan2
- ABHD18 | c.623C>T p.A208V (on ENST00000398965 / NM_001039717.2; = p.A81V on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761660121, COSV66294178; called by muse, mutect2, varscan2
- ABHD6 | c.452G>A p.G151D | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55910003; called by muse, varscan2
- ABI1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs754848112, COSV61019891; called by muse, mutect2, varscan2
- ABI3BP | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.978); catalogued as rs1287946432, COSV99428617; called by muse, mutect2, varscan2
- ABLIM1 | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs1318946298; called by muse, mutect2, varscan2
- ABLIM1 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs763448342; called by muse, mutect2, varscan2
- ABRAXAS2 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs767502502, COSV53716224; called by muse, mutect2, varscan2
- ABTB2 | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as rs768924667, COSV54390792; called by mutect2, varscan2
- AC013477.1 | c.2614G>A p.A872T | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as rs558905999, COSV53654513, COSV53655900; called by muse, mutect2, varscan2
- AC068580.4 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.959); catalogued as COSV52587065; called by muse, mutect2, varscan2
- AC126283.2 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs751111134, CM1311006; called by muse, mutect2, varscan2
- ACACA | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs187880919; called by muse, mutect2, varscan2
- ACACB | c.1337G>T p.R446I | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV58128531; called by muse, varscan2
- ACACB | c.2921C>T p.P974L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as rs768264013, COSV58132217, COSV58140761; called by muse, mutect2, varscan2
- ACAD11 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1174289663; called by muse, mutect2, varscan2
- ACAN | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.067); catalogued as COSV100718122; called by muse, mutect2, varscan2
- ACAN | c.6482C>T p.A2161V | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.405); catalogued as rs764318576, COSV61356917; called by muse, mutect2, varscan2
- ACCS | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs776507293; called by muse, mutect2, varscan2
- ACCSL | c.1533G>T p.K511N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs997822215; called by muse, mutect2, varscan2
- ACE2 | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99382558; called by muse, mutect2, varscan2
- ACER3 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs755357196, COSV99568398; called by muse, mutect2, varscan2
- ACIN1 | c.2260T>C p.S754P | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV99400351; called by muse, mutect2, varscan2
- ACKR3 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.063); catalogued as rs201643093; called by muse, mutect2, varscan2
- ACKR3 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs558720877, COSV56024105; called by muse, mutect2, varscan2
- ACKR4 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1398393923, COSV51442163; called by muse, mutect2, varscan2
- ACO2 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.916); catalogued as rs147361669, COSV99347680; called by muse, varscan2
- ACOT13 | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148153546; called by muse, mutect2, varscan2
- ACOT7 | c.1090C>T p.R364W (on ENST00000377855 / NM_181864.3; = p.R354W on NM_007274.4) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781024703, COSV64111974; called by mutect2, varscan2
- ACOT7 | c.602G>A p.R201H (on ENST00000377855 / NM_181864.3; = p.R191H on NM_007274.4) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64112502; called by muse, mutect2, varscan2
- ACOX2 | c.1783G>A p.A595T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as rs1416209921, COSV57149671; called by muse, mutect2, varscan2
- ACOX2 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs759724683; called by muse, mutect2, varscan2
- ACOX2 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs145060799; called by muse, mutect2, varscan2
- ACP2 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); catalogued as rs776312283; called by muse, varscan2
- ACP5 | c.192C>A p.D64E | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs766000656; called by muse, mutect2, varscan2
- ACP7 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.646); catalogued as COSV58699753; called by muse, varscan2
- ACRBP | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs367723803, COSV57523582; called by muse, mutect2, varscan2
- ACSBG1 | c.92A>G p.D31G | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs946162923; called by muse, mutect2, varscan2
- ACTL6B | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs780636767, COSV50518996; called by muse, mutect2, varscan2
- ACTN2 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs767041933, COSV63974905; called by mutect2, varscan2
- ACTN3 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs374716398; called by muse, mutect2, varscan2
- ACTN3 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.055); catalogued as rs778038749; called by muse, varscan2
- ACTN4 | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as rs760946329; called by muse, mutect2, varscan2
- ACTR2 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53202628; called by muse, mutect2, varscan2
- ACTR3B | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1162816026, COSV55447175, COSV99753974; called by muse, mutect2, varscan2
- ACTR5 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780725473, COSV54760677, COSV54760819; called by muse, mutect2, varscan2
- ACVR1B | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243575055; called by muse, mutect2, varscan2
- ADA2 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.413); catalogued as rs757839578, COSV52832350; called by muse, mutect2, varscan2
- ADAD2 | c.1631C>T p.T544I (on ENST00000315906 / NM_001145400.2; = p.T626I on NM_139174.4) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs956443302; called by muse, mutect2, varscan2
- ADAM10 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs754468638; called by muse, varscan2
- ADAM12 | c.1772G>A p.R591Q | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs150641628; called by muse, mutect2, varscan2
- ADAM12 | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.08); catalogued as rs376021623; called by muse, mutect2, varscan2
- ADAM19 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178207005, COSV57436288; called by muse, mutect2, varscan2
- ADAM23 | c.1068G>T p.K356N | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.665); catalogued as COSV52223628; called by muse, mutect2, varscan2
- ADAM29 | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs750050614, COSV63661362; called by muse, mutect2, varscan2
- ADAM29 | c.1663C>T p.Q555* | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | catalogued as COSV63669236; called by muse, mutect2, varscan2
- ADAM32 | c.1071G>T p.K357N | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101165387; called by muse, mutect2, varscan2
- ADAM7 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs149722616; called by muse, varscan2
- ADAM7 | c.1393G>T p.D465Y | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV51534609; called by muse, mutect2, varscan2
- ADAM9 | c.2336C>T p.A779V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as rs909215861; called by muse, mutect2, varscan2
- ADAMTS10 | c.2335C>T p.R779* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV54351845; called by muse, mutect2, varscan2
- ADAMTS12 | c.3904G>A p.A1302T | Missense Mutation (SNP) | VAF 84/182 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.141); catalogued as COSV61282093; called by muse, mutect2, varscan2
- ADAMTS12 | c.2012G>A p.G671D | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61277989; called by muse, mutect2, varscan2
- ADAMTS12 | c.1250A>G p.Y417C | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1469328760; called by muse, mutect2, varscan2
- ADAMTS17 | c.3211C>T p.R1071W | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773331594, COSV51492534; called by muse, mutect2, varscan2
- ADAMTS18 | c.2189G>A p.G730D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV51423806; called by muse, mutect2, varscan2
- ADAMTS18 | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as rs1159537536, COSV51400811; called by muse, mutect2, varscan2
- ADAMTS2 | c.2733G>T p.Q911H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as rs770035573, COSV52377384; called by muse, varscan2
- ADAMTS2 | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs200806292; called by muse, mutect2, varscan2
- ADAMTS20 | c.2833G>A p.D945N | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as COSV67136422; called by muse, mutect2, varscan2
- ADAMTS20 | c.993G>T p.K331N | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs370008149, COSV67130141; called by muse, mutect2, varscan2
- ADAMTS9 | c.3004C>T p.R1002C | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs769237592, COSV99899519; called by muse, mutect2, varscan2
- ADAMTS9 | c.2311C>T p.R771* | Nonsense Mutation (SNP) | VAF 27/86 reads (31%) | catalogued as COSV55780508; called by muse, mutect2, varscan2
- ADAMTSL1 | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542908248; called by muse, varscan2
- ADAMTSL2 | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs758219925; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4942C>T p.R1648W | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs774833128; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2009G>A p.R670Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.147); catalogued as rs763764814, COSV99646739; called by muse, mutect2, varscan2
- ADAP2 | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as rs772979991; called by muse, mutect2, varscan2
- ADAP2 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs201799866, COSV58296477; called by muse, mutect2, varscan2
- ADAR | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as rs958924655, COSV52719527; called by muse, mutect2, varscan2
- ADCK5 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1417049920, COSV58235007; called by muse, mutect2, varscan2
- ADCY1 | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs748614348, COSV52030450; called by muse, mutect2, varscan2
- ADCY3 | c.2653C>T p.R885* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as COSV53165881; called by muse, varscan2
- ADCY9 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as rs755805807; called by muse, varscan2
- ADCYAP1 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs8192594, COSV52485636, COSV52486264; called by muse, varscan2
- ADD1 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs374392385; called by muse, mutect2, varscan2
- ADD2 | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs781951897, COSV52461404; called by muse, mutect2, varscan2
- ADD2 | c.985C>A p.L329I | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); catalogued as COSV52459456; called by muse, mutect2, varscan2
- ADGRA2 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs373198805; called by muse, varscan2
- ADGRA2 | c.2563G>A p.V855M | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs759091895, COSV55103302; called by muse, varscan2
- ADGRA3 | c.2716G>A p.A906T | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.503); catalogued as rs754833054, COSV51560289; called by muse, mutect2, varscan2
- ADGRB1 | c.2839C>T p.P947S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60100160; called by muse, mutect2, varscan2
- ADGRB3 | c.3283G>A p.A1095T | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1311591420; called by muse, mutect2, varscan2
- ADGRB3 | c.3288-1G>T p.X1096_splice | Splice Site (SNP) | VAF 47/141 reads (33%) | catalogued as COSV53260256, COSV99487096; called by muse, mutect2, varscan2
- ADGRE3 | c.120C>A p.N40K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.028); catalogued as COSV53728182; called by muse, mutect2, varscan2
- ADGRF4 | c.1217G>A p.C406Y | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs774139040, COSV99348424; called by muse, mutect2, varscan2
- ADGRF5 | c.3172G>A p.A1058T | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as rs1307460777; called by muse, mutect2, varscan2
- ADGRG2 | c.415-1G>A p.X139_splice (on ENST00000379869 / NM_001079858.3; = p.X136_splice on NM_005756.4) | Splice Site (SNP) | VAF 26/71 reads (37%) | catalogued as rs1287737090, COSV100491931, COSV61337428; called by muse, mutect2, varscan2
- ADGRG2 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as rs760388447; called by muse, mutect2, varscan2
- ADGRG4 | c.7103C>T p.T2368M | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs1460763610, COSV54951151; called by muse, mutect2, varscan2
- ADGRG6 | c.2905C>T p.R969* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as rs753135960; called by muse, mutect2, varscan2
- ADGRG6 | c.3107A>G p.N1036S | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770281091; called by muse, varscan2
- ADGRG6 | c.3379C>T p.Q1127* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as rs747316312; called by muse, mutect2, varscan2
- ADGRG7 | c.2339C>T p.P780L | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs765888895, COSV56293266; called by muse, varscan2
- ADGRL1 | c.2550+1G>A p.X850_splice (on ENST00000340736 / NM_001008701.3; = p.X845_splice on NM_014921.5) | Splice Site (SNP) | VAF 9/24 reads (38%) | catalogued as COSV61563460; called by muse, mutect2, varscan2
- ADGRL1 | c.985C>T p.R329C (on ENST00000340736 / NM_001008701.3; = p.R324C on NM_014921.5) | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1300020864; called by muse, mutect2, varscan2
- ADGRL2 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780914901; called by muse, mutect2, varscan2
- ADGRL2 | c.3124G>A p.A1042T (on ENST00000370717 / NM_001366005.1; = p.A1029T on NM_012302.4) | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.182); catalogued as rs373385024; called by muse, mutect2, varscan2
- ADGRL3 | c.3215G>T p.R1072M (on ENST00000506720 / NM_001322402.2; = p.R1004M on NM_015236.6) | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV72230729; called by muse, mutect2, varscan2
- ADGRV1 | c.1820G>A p.G607E | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV67988413; called by muse, mutect2, varscan2
- ADGRV1 | c.10606C>T p.R3536C | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs747529712, COSV67996642; called by muse, mutect2, varscan2
- ADH1C | c.966C>A p.G322= | Splice Region (SNP) | VAF 17/48 reads (35%) | catalogued as COSV101565180; called by muse, mutect2, varscan2
- ADH4 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs557732938, COSV55500215; called by muse, mutect2, varscan2
- ADIPOR1 | c.807C>T p.G269= | Splice Region (SNP) | VAF 18/44 reads (41%) | catalogued as rs763154047, COSV61851560; called by muse, varscan2
- ADIPOR1 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.701); catalogued as COSV100579462; called by muse, mutect2, varscan2
- AFAP1L2 | c.222G>A p.A74= | Splice Region (SNP) | VAF 5/22 reads (23%) | catalogued as rs1056689188; called by muse, mutect2, varscan2
- AFDN | c.1934T>C p.V645A | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.168); catalogued as rs754471752; called by muse, mutect2, varscan2
- AFDN | c.5311C>T p.R1771C (on ENST00000447894 / NM_001366320.1; = p.R1690C on NM_001207008.1) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.28); catalogued as rs529414934; called by muse, mutect2, varscan2
- AFF3 | c.3301G>A p.A1101T | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs771583669, COSV100418731; called by muse, mutect2, varscan2
- AFF3 | c.2917A>G p.M973V | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.059); catalogued as rs572833239; called by muse, mutect2, varscan2
- AFF4 | c.1144G>T p.D382Y | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV54792229; called by muse, mutect2, varscan2
- AFG1L | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs532639912, COSV64555826; called by muse, mutect2, varscan2
- AFM | c.782A>G p.D261G | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs761124562; called by muse, mutect2, varscan2
- AGAP1 | c.2312C>T p.T771M (on ENST00000304032 / NM_001037131.3; = p.T718M on NM_014914.5) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs992108060; called by muse, mutect2, varscan2
- AGAP4 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 100/222 reads (45%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as rs1223088663; called by mutect2, varscan2
- AGBL1 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs775341691, COSV69803865; called by muse, mutect2, varscan2
- AGER | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV61248874; called by muse, mutect2
- AGL | c.1253C>A p.P418H | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); catalogued as COSV99649196; called by muse, mutect2, varscan2
- AGPAT3 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs753711381; called by muse, mutect2, varscan2
- AGRN | c.5705C>T p.T1902M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.373); catalogued as rs775047750; ClinVar: uncertain significance; called by muse, varscan2
- AGTPBP1 | c.227A>G p.N76S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.125); catalogued as COSV100429644; called by muse, mutect2, varscan2
- AHCYL2 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as rs1004271912, COSV61490572; called by muse, mutect2, varscan2
- AHI1 | c.3364C>T p.R1122* | Nonsense Mutation (SNP) | VAF 35/99 reads (35%) | catalogued as rs1487081231, COSV55630779; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHI1 | c.965G>A p.G322D | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV99662216; called by muse, mutect2, varscan2
- AHNAK | c.13682G>A p.G4561D | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs12795508; called by muse, mutect2, varscan2
- AHNAK | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1211319203, COSV57205263; called by muse, mutect2, varscan2
- AHRR | c.1870G>A p.G624S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.022); catalogued as rs758412461; called by muse, varscan2
- AICDA | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV57563615; called by muse, mutect2, varscan2
- AIM2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs781190100; called by muse, mutect2, varscan2
- AK8 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as rs866903749; called by muse, mutect2, varscan2
- AKAP17A | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58308707; called by muse, mutect2, varscan2
- AKAP5 | c.413G>T p.R138M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs764945303; called by mutect2, varscan2
- AKAP6 | c.4222G>A p.V1408M | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.014); catalogued as COSV55212244; called by muse, varscan2
- AKAP7 | c.236dup p.R80Efs*24 | Frame Shift Ins (INS) | VAF 26/68 reads (38%) | catalogued as rs763109484; called by mutect2, varscan2
- AKAP9 | c.6572C>T p.A2191V (on ENST00000359028; = p.A2159V on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772512812, COSV62355873; called by muse, mutect2, varscan2
- AKNA | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs369748755; called by muse, varscan2
- AKR7A3 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.379); catalogued as rs369669956; called by muse, mutect2, varscan2
- AL031315.1 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as rs776557108; called by muse, mutect2, varscan2
- AL133500.1 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated, low confidence (0.16); catalogued as rs751916691, COSV99860492; called by muse, mutect2, varscan2
- AL592490.1 | c.1607T>G p.L536R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV101308185; called by muse, mutect2, varscan2
- ALDH18A1 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756168752; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH1A3 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs770345049, COSV60903281; called by muse, varscan2
- ALDH1L1 | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs768309358, COSV56414649; called by muse, mutect2, varscan2
- ALDH1L2 | c.2566G>A p.A856T | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1180751025; called by muse, mutect2, varscan2
- ALDH1L2 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs993159070, COSV51553538; called by muse, mutect2, varscan2
- ALDH8A1 | c.1232G>T p.R411I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.098); catalogued as COSV99664591; called by muse, mutect2, varscan2
- ALG10 | c.617C>T p.T206M | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.553); catalogued as rs372903050, COSV56792218; called by muse, mutect2, varscan2
- ALG10B | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 79/165 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs570861653, COSV58143926; called by muse, mutect2, varscan2
- ALG11 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs575212926, COSV73000708; called by muse, mutect2, varscan2
- ALG12 | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 13/25 reads (52%) | PolyPhen benign (0); catalogued as rs938305311; called by muse, mutect2, varscan2
- ALG12 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 16/35 reads (46%) | PolyPhen benign (0.015); catalogued as rs778171596, COSV58208620; called by muse, mutect2, varscan2
- ALG3 | c.1015G>A p.V339I | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as rs1323127252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALG9 | c.1421G>A p.R474Q (on ENST00000614444 / NM_001352418.1; = p.R481Q on NM_024740.2) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555118614; called by muse, varscan2
- ALKBH2 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs755086747; called by muse, varscan2
- ALLC | c.655A>C p.N219H | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as COSV99378266; called by muse, mutect2, varscan2
- ALMS1 | c.11077A>T p.K3693* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as CM074695; called by muse, mutect2
- ALOX12 | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs758721831, COSV52350990; called by muse, mutect2, varscan2
- ALOX5 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.794); catalogued as rs1454834689, COSV65551681; called by muse, mutect2, varscan2
- ALPK1 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs761316245; called by muse, varscan2
- ALPK1 | c.3262G>A p.A1088T | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs551402838, COSV51584665, COSV99455002; called by muse, mutect2, varscan2
- ALPK3 | c.1979G>T p.G660V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as rs750283759; called by muse, mutect2, varscan2
- ALPK3 | c.5113C>T p.R1705W | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs143300163; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMACR | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as rs1386707127, COSV59460282; called by muse, mutect2, varscan2
- AMBRA1 | c.3554G>A p.S1185N (on ENST00000458649 / NM_001367468.1; = p.S1095N on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV54049282; called by muse, mutect2, varscan2
- AMER3 | c.1816C>T p.R606* | Nonsense Mutation (SNP) | VAF 15/29 reads (52%) | catalogued as rs781541050, COSV100365992; called by muse, mutect2, varscan2
- AMMECR1L | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV55760188, COSV99761263; called by muse, mutect2, varscan2
- AMPD1 | c.1129C>A p.L377I | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs377513152; called by muse, varscan2
- AMPD1 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs548608037, COSV100814902; called by muse, varscan2
- AMPD2 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.613); catalogued as rs150418456; called by muse, varscan2
- AMPD2 | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV56648847; called by muse, mutect2, varscan2
- AMPD3 | c.505G>A p.A169T (on ENST00000396553 / NM_001025389.2; = p.A178T on NM_000480.3) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs779211791, COSV67332404; called by muse, mutect2, varscan2
- AMPD3 | c.1691C>T p.A564V (on ENST00000396553 / NM_001025389.2; = p.A573V on NM_000480.3) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as rs1352951203, COSV67331859; called by muse, mutect2, varscan2
- AMY2B | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 99/257 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs558718174; called by muse, mutect2, varscan2
- AMY2B | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 109/263 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs201396892; called by muse, mutect2, varscan2
- AMY2B | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1258153762; called by muse, mutect2, varscan2
- ANAPC5 | c.1624G>T p.E542* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as COSV55844089; called by muse, mutect2, varscan2
- ANAPC5 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1555273362; called by muse, mutect2, varscan2
- ANAPC7 | c.1075C>T p.L359F | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV101482846; called by muse, varscan2
- ANGEL2 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0.043); catalogued as COSV100853999; called by muse, mutect2, varscan2
- ANGPT2 | c.1028A>C p.K343T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1254250739; called by muse, mutect2, varscan2
- ANGPTL1 | c.1369G>T p.G457* | Nonsense Mutation (SNP) | VAF 48/97 reads (49%) | catalogued as COSV52367098; called by muse, mutect2, varscan2
- ANGPTL1 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.065); catalogued as rs1008176981, COSV52367362; called by muse, mutect2
- ANGPTL2 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.318); catalogued as rs776774899, COSV99402982; called by muse, mutect2, varscan2
- ANGPTL2 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1370237479; called by muse, mutect2, varscan2
- ANK1 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs200898069; called by muse, varscan2
- ANK2 | c.8098G>A p.D2700N | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.998); catalogued as rs1275616940; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.1940C>T p.A647V | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs1017693748; called by muse, mutect2, varscan2
- ANKEF1 | c.626G>A p.G209D | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV101001054; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1508A>C p.E503A | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51850936; called by muse, mutect2, varscan2
- ANKK1 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs763014604, COSV58271854; called by muse, mutect2, varscan2
- ANKK1 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs558913172, COSV58274560; called by muse, varscan2
- ANKLE2 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1001373555, COSV61709039; called by muse, mutect2, varscan2
- ANKLE2 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs745348245, COSV61711053; called by muse, mutect2, varscan2
- ANKRD13B | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.464); catalogued as rs1403646075, COSV100801076; called by muse, mutect2, varscan2
- ANKRD13B | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs765679822; called by muse, mutect2, varscan2
- ANKRD13C | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 18/63 reads (29%) | catalogued as COSV52029052; called by muse, mutect2, varscan2
- ANKRD13C | c.912A>G p.I304M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as rs1247059913; called by muse, mutect2, varscan2
- ANKRD20A2P | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs557549890; called by mutect2, varscan2
- ANKRD26 | c.2929C>T p.R977W | Missense Mutation (SNP) | VAF 89/201 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs766543259; called by muse, mutect2, varscan2
- ANKRD28 | c.2066C>T p.A689V | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs768054447, COSV67518408; called by muse, mutect2, varscan2
- ANKRD34B | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 34/77 reads (44%) | catalogued as COSV58613404; called by muse, mutect2, varscan2
- ANKRD34B | c.446T>C p.I149T | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1343997090; called by muse, varscan2
- ANKRD34B | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1466520834; called by muse, varscan2
- ANKRD36 | c.299C>T p.T100I | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV101347382; called by muse, mutect2, varscan2
- ANKRD36B | c.2983C>T p.R995W | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.317); catalogued as rs1271378769; called by mutect2, varscan2
- ANKRD44 | c.2457T>G p.C819W | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1352195062; called by muse, mutect2, varscan2
- ANKRD52 | c.2656G>A p.A886T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as rs766786981; called by muse, varscan2
- ANKRD55 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1206760744; called by muse, mutect2, varscan2
- ANKRD55 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144108986; called by muse, mutect2, varscan2
- ANKS1A | c.2605C>T p.R869W | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as rs541932194, COSV64462458; called by muse, mutect2, varscan2
- ANKZF1 | c.558+1G>A p.X186_splice | Splice Site (SNP) | VAF 12/39 reads (31%) | catalogued as rs763682835; called by muse, mutect2, varscan2
- ANLN | c.3119G>A p.R1040H | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs151288243; called by muse, mutect2, varscan2
- ANO2 | c.1667G>A p.R556Q (on ENST00000356134 / NM_001278597.3; = p.R560Q on NM_001278596.3) | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs773771654, COSV59020666; called by muse, varscan2
- ANO2 | c.901G>A p.A301T (on ENST00000356134 / NM_001278597.3; = p.A305T on NM_001278596.3) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as rs752172270; called by muse, varscan2
- ANO3 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.005); catalogued as rs777889841, COSV56783616; called by muse, mutect2, varscan2
- ANO4 | c.2369C>T p.A790V (on ENST00000392977 / NM_001286615.2; = p.A755V on NM_178826.4) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763712389, COSV100151981; called by muse, mutect2, varscan2
- ANO5 | c.2005C>T p.L669F | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61084185; called by muse, mutect2, varscan2
- ANO6 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.046); catalogued as rs747667835, COSV57664976; called by muse, mutect2, varscan2
- ANOS1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as rs1404298787, COSV52916162; called by muse, varscan2
- ANPEP | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs367926309; called by muse, mutect2, varscan2
- ANPEP | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs774575427, COSV100263219; called by muse, mutect2, varscan2
- ANPEP | c.659C>A p.S220Y | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1236013690, COSV55593816; called by muse, mutect2, varscan2
- ANXA10 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 49/95 reads (52%) | catalogued as rs1192134579, COSV100829098; called by muse, mutect2, varscan2
- ANXA6 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759582371; called by muse, mutect2, varscan2
- ANXA8 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 78/99 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1220680586; called by muse, mutect2, varscan2
- AOC1 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762601763; called by muse, mutect2, varscan2
- AP1B1 | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs773139106; called by muse, mutect2, varscan2
- AP1M1 | c.199+1G>A p.X67_splice | Splice Site (SNP) | VAF 33/71 reads (46%) | catalogued as rs1461259560, COSV52227054; called by muse, mutect2, varscan2
- AP1M2 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.689); catalogued as rs368585156; called by muse, mutect2
- AP3D1 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs756366949, COSV61432622; called by muse, mutect2, varscan2
- AP4M1 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs565296810; called by muse, mutect2, varscan2
- APBA1 | c.2468C>T p.A823V | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs1476460860; called by muse, mutect2, varscan2
- APBA1 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs760771546, COSV55226831; called by muse, mutect2, varscan2
- APBA2 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs145833994, COSV104435541; called by muse, varscan2
- APBA3 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs894378369; called by muse, mutect2, varscan2
- APBB2 | c.2141C>T p.P714L (on ENST00000295974 / NM_001166050.2; = p.P715L on NM_004307.2) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766487790; called by muse, mutect2, varscan2
- APBB3 | c.457A>G p.T153A | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV60054508; called by muse, mutect2, varscan2
- APC | c.701T>G p.L234R | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs1309846315; called by muse, mutect2, varscan2
- APC | c.2357G>A p.R786H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.948); catalogued as rs1554084088, COSV99971689; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.6920C>T p.S2307L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs901983934, COSV57330138; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APEX2 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as rs749036434, COSV66623956; called by muse, mutect2, varscan2
- APLNR | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs374221224, COSV99951271; called by muse, varscan2
- APOB | c.13054C>A p.L4352I | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.036); catalogued as COSV99263788; called by muse, varscan2
- APOB | c.4537C>T p.R1513W | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs139621265; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 31/68 reads (46%) | catalogued as COSV51923448, COSV51943073; called by muse, mutect2, varscan2
- APOBEC1 | c.207del p.K69Nfs*12 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | catalogued as rs753365818; called by mutect2, pindel, varscan2
- APOBEC3B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV59841198; called by muse, mutect2, varscan2
- APOBEC3G | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.221); catalogued as rs775955420, COSV68469989; called by muse, mutect2, varscan2
- APOBEC3G | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.806); catalogued as rs142924244; called by muse, mutect2, varscan2
- APOBEC3G | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as rs552054727, COSV68470300; called by muse, mutect2, varscan2
- APOBEC4 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV58018301; called by muse, mutect2
- APOF | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs578174811; called by muse, mutect2, varscan2
- APOL2 | c.240G>A p.W80* | Nonsense Mutation (SNP) | VAF 33/70 reads (47%) | catalogued as rs759529102; called by muse, mutect2, varscan2
- APOL5 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs763219644, COSV50766586; called by muse, mutect2, varscan2
- APP | c.2189C>T p.S730F | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV60993490; called by muse, mutect2, varscan2
- APPBP2 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.745); catalogued as rs1423578353; called by muse, mutect2, varscan2
- APPBP2 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs760914598, COSV99319389; called by muse, mutect2, varscan2
- APPL1 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV55699692; called by muse, mutect2, varscan2
- AR | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.012); catalogued as rs749006575, COSV65957404, COSV65963977; called by muse, mutect2, varscan2
- AR | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1274441708, COSV65957646; called by muse, mutect2, varscan2
- ARAP2 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); catalogued as COSV58290369; called by muse, mutect2, varscan2
- ARAP3 | c.3395A>G p.N1132S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs749857920; called by muse, mutect2, varscan2
- ARAP3 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs769233152; called by muse, mutect2, varscan2
- ARCN1 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs1371890885; called by muse, mutect2, varscan2
- AREG | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1219113338; called by muse, mutect2, varscan2
- AREL1 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs757996581, COSV100707656; called by muse, mutect2, varscan2
- ARFGAP2 | c.1447G>A p.V483M | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs748232896, COSV53565261; called by muse, mutect2, varscan2
- ARFGAP2 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1193629451, COSV60301904; called by muse, mutect2, varscan2
- ARFGEF1 | c.5353C>A p.L1785I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.947); catalogued as COSV51589614; called by muse, mutect2, varscan2
- ARFGEF1 | c.3736C>T p.R1246W | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1253162847; called by muse, mutect2, varscan2
- ARFGEF1 | c.3253G>T p.D1085Y | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV99141445; called by muse, mutect2, varscan2
- ARFGEF1 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1563894275; called by muse, mutect2, varscan2
- ARFGEF2 | c.4331C>T p.A1444V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766953564, COSV100904282; called by muse, mutect2, varscan2
- ARHGAP17 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs768561975; called by muse, mutect2
- ARHGAP19 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760723887, COSV57396354; called by muse, mutect2, varscan2
- ARHGAP20 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs770770539, COSV52811716; called by muse, varscan2
- ARHGAP21 | c.5509C>T p.R1837W | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs151326840; called by muse, mutect2, varscan2
- ARHGAP21 | c.4559G>A p.R1520H | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs754482786, COSV57605277; called by muse, mutect2, varscan2
- ARHGAP21 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 107/223 reads (48%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.575); catalogued as rs1437208309; called by muse, mutect2, varscan2
- ARHGAP21 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs781204657; called by muse, mutect2, varscan2
- ARHGAP24 | c.481G>A p.D161N (on ENST00000395184 / NM_001025616.3; = p.D68N on NM_031305.3) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1388808126, COSV99982464; called by muse, mutect2, varscan2
- ARHGAP24 | c.893G>A p.R298H (on ENST00000395184 / NM_001025616.3; = p.R205H on NM_031305.3) | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1007199761, COSV51988098; called by muse, mutect2, varscan2
- ARHGAP24 | c.2104C>T p.R702* (on ENST00000395184 / NM_001025616.3; = p.R609* on NM_031305.3) | Nonsense Mutation (SNP) | VAF 28/57 reads (49%) | catalogued as rs376118883; called by muse, mutect2, varscan2
- ARHGAP25 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs1436545414; called by muse, mutect2, varscan2
- ARHGAP25 | c.991G>A p.V331M (on ENST00000409202 / NM_001007231.3; = p.V323M on NM_014882.3) | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as rs745617834; called by muse, mutect2, varscan2
- ARHGAP30 | c.3188G>A p.R1063Q (on ENST00000368013 / NM_001025598.2; = p.R852Q on NM_181720.3) | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.398); catalogued as rs200017624, COSV63515091, COSV63518541; called by muse, mutect2, varscan2
- ARHGAP35 | c.1585C>T p.R529* | Nonsense Mutation (SNP) | VAF 24/50 reads (48%) | catalogued as COSV68328962; called by muse, mutect2, varscan2
- ARHGAP4 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); catalogued as rs968228828; called by muse, mutect2, varscan2
- ARHGAP45 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV99075549; called by muse, mutect2, varscan2
- ARHGEF10 | c.1144G>A p.A382T (on ENST00000398564; = p.A357T on NM_014629.4) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs749096672; called by muse, mutect2
- ARHGEF10L | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as rs773305597; called by muse, varscan2
- ARHGEF10L | c.2342C>T p.P781L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs368062395, COSV99391864; called by muse, varscan2
- ARHGEF11 | c.2768C>T p.A923V | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1420230862, COSV59356893; called by muse, mutect2, varscan2
- ARHGEF11 | c.2339C>T p.P780L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs747246966, COSV59359584; called by muse, mutect2, varscan2
- ARHGEF11 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771043193; called by muse, mutect2, varscan2
- ARHGEF11 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs375264879; called by muse, mutect2, varscan2
- ARHGEF15 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as rs769480435; called by muse, varscan2
- ARHGEF17 | c.3917G>A p.R1306Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs748158033; called by muse, varscan2
- ARHGEF18 | c.1108C>T p.R370C (on ENST00000359920 / NM_001130955.2; = p.R266C on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766437964; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF26 | c.1203G>T p.Q401H | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV62844036; called by muse, mutect2, varscan2
- ARHGEF28 | c.3200C>T p.T1067M | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs549311828; called by muse, varscan2
- ARHGEF28 | c.3204G>T p.K1068N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs774856299, COSV55265793; called by muse, varscan2
- ARHGEF3 | c.993C>A p.S331R | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV56327496; called by muse, mutect2, varscan2
- ARHGEF40 | c.2312G>A p.R771H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.642); catalogued as rs761052679; called by muse, varscan2
- ARHGEF5 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs564658226, COSV99282579; called by muse, mutect2, varscan2
- ARHGEF6 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51688598; called by muse, mutect2, varscan2
- ARID1A | c.4840C>T p.Q1614* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV61380458; called by muse, mutect2, varscan2
- ARID1B | c.1984C>T p.P662S | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99272389; called by muse, mutect2, varscan2
- ARID1B | c.2936C>T p.T979M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as rs1247824233; called by muse, mutect2, varscan2
- ARID1B | c.3915G>A p.M1305I | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as rs757999037; called by muse, mutect2, varscan2
- ARID1B | c.5495G>A p.R1832H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs374035954; called by muse, varscan2
- ARID2 | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV57612571, COSV57613003; called by muse, mutect2, varscan2
- ARID2 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs896638040, COSV57600821, COSV57606795; called by muse, mutect2, varscan2
- ARID2 | c.4612A>G p.I1538V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs1176843459; called by muse, mutect2, varscan2
- ARID4A | c.3077C>T p.T1026M | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200034672; called by muse, mutect2, varscan2
- ARID4B | c.1042C>T p.H348Y | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.908); catalogued as rs991074963; called by muse, mutect2
- ARID5B | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as rs550591609, COSV99688722; called by muse, mutect2, varscan2
- ARIH1 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs753804913; called by muse, mutect2, varscan2
- ARL2 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs753529299; called by muse, varscan2
- ARMC3 | c.1261G>A p.V421I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.73); catalogued as rs572510134; called by muse, mutect2, varscan2
- ARMH4 | c.2256G>T p.K752N | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50771875; called by muse, mutect2, varscan2
- ARMH4 | c.1866A>C p.E622D | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as rs376833564; called by muse, mutect2, varscan2
- ARMH4 | c.1472G>A p.S491N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV50773188; called by muse, mutect2, varscan2
- ARMH4 | c.1190C>A p.S397Y | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV50767350, COSV99958351; called by muse, mutect2, varscan2
- ARMH4 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs572339718, COSV50761758; called by muse, mutect2, varscan2
- ARNT2 | c.566C>A p.P189H | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57584891, COSV57590044; called by muse, mutect2, varscan2
- ARPC3 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs770287826; called by muse, mutect2, varscan2
- ARRB2 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.787); catalogued as rs377694460; called by muse, varscan2
- ARRB2 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as rs780961076, COSV52618024; called by muse, mutect2, varscan2
- ARRDC4 | c.403T>C p.Y135H | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.193); catalogued as COSV51419714; called by muse, mutect2, varscan2
- ARSG | c.1465G>A p.V489I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs373638226; called by mutect2, varscan2
- ARSH | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 82/207 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.031); catalogued as rs1279616557, COSV66963800; called by muse, mutect2, varscan2
- ARSI | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.154); catalogued as rs763136370, COSV60817209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARSI | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1175590084, COSV60816824; called by muse, mutect2, varscan2
- ARV1 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as rs144095931; called by muse, mutect2, varscan2
- ASAP2 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 70/141 reads (50%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.457); catalogued as rs1051207873; called by muse, mutect2, varscan2
- ASB13 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs564380910, COSV63090904; called by muse, mutect2, varscan2
- ASB13 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); catalogued as rs757058806, COSV63092204; called by muse, mutect2, varscan2
- ASCC3 | c.2647C>T p.R883* | Nonsense Mutation (SNP) | VAF 31/93 reads (33%) | catalogued as COSV61228203; called by muse, mutect2, varscan2
- ASH1L | c.4478G>A p.R1493H | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.379); catalogued as rs184705228; called by muse, mutect2, varscan2
- ASH1L | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 69/199 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs374072309; called by muse, mutect2, varscan2
- ASH2L | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.867); catalogued as rs747978296; called by muse, mutect2, varscan2
- ASMT | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.563); catalogued as rs763888040; called by muse, mutect2, varscan2
- ASMTL | c.1123G>A p.G375S | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.718); catalogued as rs199829721, COSV67244780; called by muse, mutect2
- ASMTL | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 92/103 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1349311941, COSV101187777; called by muse, mutect2, varscan2
- ASNSD1 | c.414dup p.G139Wfs*4 | Frame Shift Ins (INS) | VAF 6/14 reads (43%) | catalogued as rs759722534; called by mutect2, varscan2
- ASPM | c.6796G>A p.A2266T | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200800956; called by muse, mutect2, varscan2
- ASPM | c.2257C>A p.L753I | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1443352278; called by muse, varscan2
- ASS1 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs150466363; called by muse, varscan2
- ASTN2 | c.2927G>A p.R976H (on ENST00000313400 / NM_001365069.1; = p.R925H on NM_014010.5) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs148503875; called by muse, mutect2, varscan2
- ASTN2 | c.1898C>T p.A633V (on ENST00000313400 / NM_001365069.1; = p.A582V on NM_014010.5) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs752461666, COSV57818498; called by muse, mutect2, varscan2
- ASXL1 | c.565G>T p.G189W | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV60108151; called by muse, varscan2
- ASZ1 | c.929A>G p.E310G | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs748730818; called by muse, varscan2
- ATAD2 | c.4030dup p.S1344Kfs*28 | Frame Shift Ins (INS) | VAF 18/52 reads (35%) | catalogued as rs775812316; called by mutect2, varscan2
- ATAD5 | c.4874C>A p.S1625Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs1383788837; called by muse, mutect2, varscan2
- ATCAY | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs199582357; called by muse, mutect2, varscan2
- ATF6 | c.85T>C p.S29P | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.942); catalogued as rs1179230713; called by muse, mutect2, varscan2
- ATF7 | c.1043G>A p.R348H (on ENST00000548446 / NM_001366555.2; = p.R337H on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs760791156; called by muse, mutect2, varscan2
- ATF7IP2 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs140651559; called by muse, mutect2, varscan2
- ATF7IP2 | c.1990C>T p.R664* | Nonsense Mutation (SNP) | VAF 31/75 reads (41%) | catalogued as COSV100202613; called by muse, mutect2, varscan2
- ATG14 | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs753707798, COSV55955372; called by muse, varscan2
- ATG14 | c.1231G>A p.G411R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs865972356; called by muse, varscan2
- ATG2B | c.3349C>A p.L1117M | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as COSV100738162; called by muse, mutect2, varscan2
- ATG2B | c.1221C>A p.F407L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV63425684; called by muse, varscan2
- ATG9A | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1376695742; called by muse, varscan2
- ATL1 | c.1111del p.M371Wfs*29 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as rs1566733927; called by mutect2, pindel, varscan2
- ATN1 | c.3004C>T p.R1002C | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1555144312, COSV63110253; called by muse, mutect2, varscan2
- ATP10A | c.2303C>T p.A768V | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63517264; called by muse, mutect2, varscan2
- ATP10A | c.2012G>A p.S671N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as COSV100791034; called by mutect2, varscan2
- ATP10B | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1046060906; called by muse, mutect2, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 44/62 reads (71%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP11B | c.3363C>A p.C1121* | Nonsense Mutation (SNP) | VAF 35/78 reads (45%) | catalogued as COSV60025702; called by muse, mutect2, varscan2
- ATP11C | c.2232G>A p.W744* | Nonsense Mutation (SNP) | VAF 41/79 reads (52%) | catalogued as COSV59572490; called by muse, mutect2, varscan2
- ATP11C | c.503G>A p.C168Y | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.612); catalogued as COSV59559411; called by muse, mutect2, varscan2
- ATP13A1 | c.2047G>A p.A683T | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs753084546; called by muse, varscan2
- ATP13A3 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs755718276, COSV55462722; called by muse, mutect2, varscan2
- ATP13A5 | c.3524G>T p.R1175M | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV53230270; called by muse, mutect2, varscan2
- ATP13A5 | c.1256T>C p.V419A | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.633); catalogued as COSV60866549; called by muse, mutect2, varscan2
- ATP13A5 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as rs776857987; called by muse, mutect2, varscan2
- ATP13A5 | c.324A>C p.E108D | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV60870354; called by muse, mutect2, varscan2
- ATP1A1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as rs139745455; called by muse, mutect2, varscan2
- ATP1A2 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 20/34 reads (59%) | catalogued as rs760155608, COSV63405678; called by muse, mutect2, varscan2
- ATP1A3 | c.1514G>A p.R505Q (on ENST00000545399 / NM_001256214.2; = p.R492Q on NM_152296.5) | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs564392504; called by muse, mutect2, varscan2
- ATP1B4 | c.912C>T p.H304= (on ENST00000218008 / NM_001142447.3; = p.H300= on NM_012069.5) | Splice Region (SNP) | VAF 20/55 reads (36%) | catalogued as rs368849098; called by muse, mutect2, varscan2
- ATP2A2 | c.1855C>T p.R619W | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs1201260065, COSV57876442; called by muse, mutect2, varscan2
- ATP2A2 | c.1978C>T p.L660F | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV57875432; called by muse, mutect2, varscan2
- ATP2A2 | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs886048953, COSV57875184; ClinVar: uncertain significance; called by muse, mutect2
- ATP2B1 | c.3419C>T p.S1140L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53803716; called by muse, varscan2
- ATP2B2 | c.1757A>G p.Y586C (on ENST00000352432; = p.Y552C on NM_001683.5) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100660702; called by muse, mutect2, varscan2
- ATP2B3 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV99686074; called by muse, mutect2, varscan2
- ATP2C1 | c.1672A>C p.T558P | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.427); catalogued as COSV60763345; called by muse, mutect2, varscan2
- ATP2C2 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs780617194, COSV52297485; called by muse, mutect2, varscan2
- ATP4A | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.142); catalogued as rs1382227785; called by muse, mutect2, varscan2
- ATP5F1B | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100008095, COSV56261268; called by muse, mutect2, varscan2
- ATP5PF | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as COSV53167142; called by muse, mutect2, varscan2
- ATP6V1B2 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52353125; called by muse, mutect2, varscan2
- ATP6V1D | c.500G>T p.R167M | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs776968392; called by muse, mutect2, varscan2
- ATP6V1H | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1484260251, COSV100778606; called by muse, mutect2, varscan2
- ATP7B | c.3964C>T p.R1322C | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs534984209; called by muse, mutect2, varscan2
- ATP7B | c.2755C>T p.R919W | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs121907993, CM980175, CM980176, COSV54437726, COSV54440244; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, varscan2
- ATP8A1 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.313); catalogued as COSV100046197; called by muse, mutect2, varscan2
- ATP8A2 | c.2158C>T p.R720* | Nonsense Mutation (SNP) | VAF 50/127 reads (39%) | catalogued as rs1566306570, COSV54964589; called by muse, mutect2, varscan2
- ATP8B4 | c.2095T>C p.F699L | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.364); catalogued as COSV52718599; called by muse, mutect2, varscan2
- ATP9A | c.2323C>T p.R775C | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs1328628299, COSV58766179; called by muse, mutect2, varscan2
- ATP9B | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 64/159 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781448227, COSV56960384; called by muse, mutect2, varscan2
- ATP9B | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs144164957; called by mutect2, varscan2
- ATP9B | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as COSV56948983; called by muse, mutect2, varscan2
- ATP9B | c.3072C>T p.G1024= | Splice Region (SNP) | VAF 19/43 reads (44%) | catalogued as rs149975826; called by muse, mutect2, varscan2
- ATRNL1 | c.3476C>T p.T1159M | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs782000658, COSV58079419, COSV58090880; called by muse, varscan2
- ATRX | c.914G>A p.S305N | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV64879708; called by muse, mutect2, varscan2
- ATXN2L | c.2185T>C p.Y729H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57368349; called by muse, mutect2, varscan2
- AVPR2 | c.331C>A p.L111M | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as CD941607; called by muse, mutect2, varscan2
- AVPR2 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs782128197, COSV100509454; called by muse, mutect2, varscan2
- AXIN1 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759464398, COSV99249418, COSV99250343; called by muse, varscan2
- AXIN2 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs372255441; called by muse, mutect2, varscan2
- B3GALT4 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs761609610; called by muse, mutect2, varscan2
- B3GALT5 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as rs144752439; called by muse, mutect2, varscan2
- B3GNT5 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58475827; called by muse, mutect2, varscan2
- B4GALNT3 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201901859, COSV56755014; called by muse, mutect2, varscan2
- B4GALNT3 | c.2113C>T p.R705C | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs192118846; called by muse, mutect2, varscan2
- B4GALT1 | c.786T>G p.C262W | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65708164; called by muse, mutect2, varscan2
- B4GALT4 | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV100785801; called by muse, mutect2, varscan2
- B4GALT6 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751234543; called by muse, mutect2, varscan2
- BACH1 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs369140615; called by muse, mutect2, varscan2
- BACH2 | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57591226; called by muse, mutect2
- BAG4 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.707); catalogued as rs770041398, COSV54861341, COSV54862630; called by muse, mutect2, varscan2
- BAHCC1 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs369663651; called by muse, mutect2, varscan2
- BAHCC1 | c.4612C>T p.R1538* | Nonsense Mutation (SNP) | VAF 11/19 reads (58%) | catalogued as COSV100311568; called by muse, mutect2, varscan2
- BAK1 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs762960717, COSV62349971; called by muse, mutect2, varscan2
- BANK1 | c.1801dup p.T601Nfs*10 | Frame Shift Ins (INS) | VAF 14/38 reads (37%) | catalogued as rs767996255; called by mutect2, varscan2
- BAZ1A | c.3598C>T p.R1200C | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1469155751, COSV100701140; called by muse, mutect2, varscan2
- BAZ1B | c.2695C>T p.R899C | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781819628; called by muse, mutect2, varscan2
- BAZ2A | c.4802A>G p.Y1601C | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200393909; called by muse, varscan2
- BAZ2B | c.4117C>T p.R1373C | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771663406; called by muse, mutect2, varscan2
- BBS10 | c.761A>G p.D254G | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV53878063; called by muse, mutect2, varscan2
- BBS12 | c.1993G>A p.V665I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs369696220, CD122050; called by muse, mutect2, varscan2
- BCL6 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.475); catalogued as rs1262719853; called by muse, mutect2, varscan2
- BCL6 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 36/81 reads (44%) | catalogued as COSV99215688; called by muse, mutect2, varscan2
- BCL7A | c.104G>T p.W35L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55847010; called by muse, mutect2, varscan2
- BCL9 | c.3725C>A p.S1242Y | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52346720; called by muse, mutect2, varscan2
- BCL9L | c.3934G>A p.E1312K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs761689835, COSV52689163; called by muse, varscan2
- BCLAF1 | c.1831T>C p.S611P | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100786722; called by muse, mutect2, varscan2
- BCLAF1 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs374912246; called by muse, mutect2, varscan2
- BCLAF3 | c.354G>T p.E118D | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV100503431; called by muse, mutect2, varscan2
- BCOR | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs745470688, COSV60715608; called by muse, mutect2, varscan2
- BCORL1 | c.1794C>A p.F598L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as COSV54400351; called by muse, varscan2
- BCORL1 | c.2939C>T p.T980M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs755857508; called by muse, varscan2
- BCORL1 | c.4354C>T p.R1452C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs758440023, COSV99499931; called by muse, mutect2, varscan2
- BDP1 | c.3952C>T p.P1318S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs751401488; called by mutect2, varscan2
- BDP1 | c.4459C>T p.P1487S | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as COSV62429458; called by muse, mutect2, varscan2
- BDP1 | c.6680C>A p.S2227Y | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.66); catalogued as COSV62429070; called by muse, mutect2, varscan2
- BEND3 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs782727307; called by muse, mutect2, varscan2
- BEX4 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as rs139178618; called by muse, mutect2, varscan2
- BEX4 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.839); catalogued as rs749945390, COSV101015391; called by muse, mutect2, varscan2
- BEX5 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV61328991; called by muse, mutect2
- BFSP2 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs747132237, COSV100183685; called by muse, mutect2, varscan2
- BHLHE40 | c.826G>A p.G276S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761570588; called by muse, mutect2, varscan2
- BICC1 | c.2678T>G p.V893G | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs770283022; called by muse, mutect2, varscan2
- BIRC6 | c.5588G>A p.R1863H | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs776988218, COSV70195731; called by muse, mutect2, varscan2
- BIRC6 | c.14015C>T p.T4672M | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70194911; called by muse, mutect2, varscan2
- BIRC6 | c.14548G>T p.E4850* | Nonsense Mutation (SNP) | VAF 21/45 reads (47%) | catalogued as COSV70202505; called by muse, mutect2, varscan2
- BLID | c.155G>A p.G52D | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.01); catalogued as rs1278103712, COSV73340298; called by muse, mutect2, varscan2
- BLNK | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as rs782667010, COSV56412399; called by muse, mutect2, varscan2
- BMP1 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs771647443; called by muse, varscan2
- BMP3 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 37/71 reads (52%) | catalogued as rs759472288; called by muse, mutect2, varscan2
- BMP3 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763946969, COSV51081761; called by muse, mutect2, varscan2
- BMPER | c.1054G>T p.G352* | Nonsense Mutation (SNP) | VAF 41/130 reads (32%) | catalogued as COSV99779747; called by muse, mutect2, varscan2
- BMPER | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51817390; called by muse, mutect2, varscan2
- BMS1 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 121/287 reads (42%) | catalogued as rs775718030, COSV100996679; called by muse, mutect2, varscan2
- BOD1L1 | c.3192G>T p.K1064N | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1183186625; called by muse, mutect2, varscan2
- BORA | c.1005dup p.Y336Ifs*8 (on ENST00000613797; = p.Y261Ifs*8 on NM_024808.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 20/70 reads (29%) | catalogued as rs757390268; called by mutect2, varscan2
- BPI | c.163G>A p.A55T (on ENST00000262865; = p.A51T on NM_001725.3) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs148247914; called by muse, mutect2, varscan2
- BPI | c.1450G>A p.V484I (on ENST00000262865; = p.V480I on NM_001725.3) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.768); catalogued as rs779376699, COSV53404935; called by muse, mutect2, varscan2
- BPIFA1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as rs767514343; called by muse, mutect2, varscan2
- BPNT2 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.72); catalogued as rs766168164; called by muse, mutect2, varscan2
- BRAP | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 29/80 reads (36%) | catalogued as COSV59537230; called by muse, varscan2
- BRCA2 | c.4178C>T p.A1393V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs398122776, COSV66448197; ClinVar: conflicting interpretations of pathogenicity / benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- BRD2 | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as rs886567754; called by muse, mutect2, varscan2
- BRD3 | c.1219G>A p.V407M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs200921972, COSV100325574, COSV57702213; called by muse, varscan2
- BRF1 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.658); catalogued as rs147106237; called by muse, varscan2
- BRI3BP | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.123); catalogued as rs1000192125, COSV58296342; called by muse, mutect2, varscan2
- BRINP1 | c.1996G>A p.A666T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.08); catalogued as rs201374834; called by muse, varscan2
- BRINP2 | c.621C>A p.S207R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs771911333; called by muse, varscan2
- BRINP3 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as rs777708418, COSV66526063; called by mutect2, varscan2
- BRINP3 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); catalogued as COSV66538626; called by muse, mutect2, varscan2
- BRINP3 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as COSV66524590; called by muse, mutect2, varscan2
- BRPF3 | c.3001G>A p.G1001S | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs765922851; called by muse, mutect2, varscan2
- BRSK2 | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.165); catalogued as rs1326757909; called by muse, mutect2, varscan2
- BSCL2 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs377609967; called by muse, mutect2, varscan2
- BTBD11 | c.3257C>T p.T1086M (on ENST00000280758 / NM_001018072.2; = p.T623M on NM_001017523.2) | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs865847862; called by muse, mutect2, varscan2
- BTBD9 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1219505965; called by muse, mutect2, varscan2
- BTBD9 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as rs1014956513, COSV58435433; called by muse, mutect2, varscan2
- BTK | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV58117776; called by muse, mutect2, varscan2
- BTK | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs141488935; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTN3A2 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 84/206 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs780484548; called by muse, mutect2, varscan2
- BTNL8 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99180598; called by muse, varscan2
- BUB3 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as COSV100922164, COSV64363886; called by muse, varscan2
- BUD23 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1002363690; called by muse, mutect2, varscan2
- C10orf90 | c.1877C>T p.T626M | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757981077, COSV52954411, COSV99505031; called by muse, varscan2
- C10orf99 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.453); catalogued as rs771262901, COSV64532232; called by muse, mutect2, varscan2
- C11orf49 | c.217dup p.H73Pfs*3 | Frame Shift Ins (INS) | VAF 44/112 reads (39%) | catalogued as rs780813798; called by mutect2, pindel, varscan2
- C12orf42 | c.1031C>T p.T344M | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as rs779166148, COSV59381064; called by muse, mutect2, varscan2
- C12orf60 | c.239A>G p.K80R | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV57451529; called by muse, varscan2
- C14orf119 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs751433100; called by muse, mutect2, varscan2
- C14orf28 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as rs749310294, COSV57333841; called by muse, mutect2, varscan2
- C15orf39 | c.458G>A p.R153K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV62298271; called by muse, mutect2, varscan2
- C16orf70 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs778233814; called by muse, mutect2, varscan2
- C16orf72 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs1389202549, COSV100588955; called by muse, varscan2
- C16orf72 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1366213938, COSV59916594; called by muse, varscan2
- C16orf78 | c.661T>G p.L221V | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54557009; called by muse, varscan2
- C17orf58 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.023); catalogued as rs782365271; called by muse, mutect2, varscan2
- C17orf75 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs563163507; called by muse, mutect2, varscan2
- C17orf78 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as rs545073498; called by muse, mutect2, varscan2
- C17orf78 | c.398dup p.L133Ffs*8 | Frame Shift Ins (INS) | VAF 32/93 reads (34%) | catalogued as rs1024564984; called by mutect2, pindel, varscan2
- C18orf54 | c.137G>T p.R46I | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV55617286; called by muse, mutect2, varscan2
- C19orf44 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs774156051, COSV99684832; called by muse, mutect2, varscan2
- C1GALT1C1 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.085); catalogued as rs762929191; called by muse, mutect2, varscan2
- C1orf100 | c.335A>G p.Q112R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1194507333; called by muse, mutect2, varscan2
- C1orf141 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760295992, COSV63993312; called by muse, mutect2, varscan2
- C1orf216 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749886240; called by muse, mutect2, varscan2
- C1orf52 | c.476-1G>A p.X159_splice | Splice Site (SNP) | VAF 24/50 reads (48%) | catalogued as COSV53998597; called by muse, mutect2, varscan2
- C20orf194 | c.3421C>T p.L1141F | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs766713302; called by muse, mutect2, varscan2
- C20orf194 | c.3335G>A p.R1112H | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.039); catalogued as rs376440074; called by muse, mutect2, varscan2
- C2CD3 | c.5335C>T p.R1779C | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.844); catalogued as rs752547363, COSV58095516; called by muse, mutect2, varscan2
- C2CD5 | c.1814G>A p.G605D | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.092); catalogued as COSV61722883; called by muse, mutect2, varscan2
- C2CD6 | c.833C>T p.T278I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as rs776476421, COSV53796858; called by muse, mutect2, varscan2
- C2orf76 | c.281G>T p.S94I | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV58346155, COSV58347254; called by muse, mutect2, varscan2
- C2orf76 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs771993808, COSV100601741; called by muse, mutect2, varscan2
- C3 | c.2746G>A p.V916I | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); catalogued as rs748941246; called by muse, mutect2, varscan2
- C3AR1 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760997627, COSV50823332; called by muse, mutect2, varscan2
- C3orf20 | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200928244; called by muse, mutect2
- C3orf33 | c.245G>A p.R82Q (on ENST00000340171 / NM_001308229.2; = p.R39Q on NM_173657.2) | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.267); catalogued as rs759430996; called by muse, mutect2, varscan2
- C6orf89 | c.452C>T p.P151L (on ENST00000373685; = p.P158L on NM_152734.4) | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV62102027; called by muse, mutect2, varscan2
- C7 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs182653194, COSV57479811; called by muse, varscan2
- C8A | c.1177G>T p.G393C | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV63486557; called by muse, mutect2, varscan2
- C8B | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as rs1557733377; called by muse, mutect2, varscan2
- C8orf34 | c.920G>A p.G307D | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.073); catalogued as COSV61369343; called by muse, mutect2, varscan2
- C8orf34 | c.1403C>A p.P468H | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100298451; called by muse, mutect2, varscan2
- C9 | c.1487G>T p.R496I | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs775670257; called by muse, mutect2, varscan2
- C9 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546890218, COSV54674723; called by muse, mutect2, varscan2
- C9orf78 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs139248631, COSV100989965; called by muse, mutect2, varscan2
- C9orf78 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as rs770685876, COSV59614045; called by muse, mutect2, varscan2
- CA13 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747534525; called by muse, mutect2, varscan2
- CA13 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749539090; called by muse, varscan2
- CA8 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58772998; called by muse, mutect2, varscan2
- CA8 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as rs746839542, COSV58771225; called by muse, mutect2, varscan2
- CABP2 | c.607C>A p.L203I | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.588); catalogued as rs762321651; called by muse, mutect2, varscan2
- CACNA1A | c.5801C>T p.A1934V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.119); catalogued as rs1483005213; called by muse, mutect2, varscan2
- CACNA1A | c.4799C>T p.A1600V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as rs1428026447; called by muse, mutect2, varscan2
- CACNA1A | c.1060C>A p.L354I | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV100802407; called by muse, mutect2, varscan2
- CACNA1D | c.3278C>T p.A1093V (on ENST00000350061 / NM_001128840.3; = p.A1113V on NM_000720.4) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs760291838; called by muse, mutect2, varscan2
- CACNA1E | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV100704440; called by muse, mutect2, varscan2
- CACNA1E | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.984); catalogued as rs757401430; called by muse, mutect2, varscan2
- CACNA1E | c.4465G>A p.A1489T | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as rs1188254439, COSV62393791; called by muse, mutect2, varscan2
- CACNA1F | c.4991C>T p.T1664M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs781998522; called by mutect2, varscan2
- CACNA1G | c.5417G>A p.G1806D | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61738867; called by muse, mutect2, varscan2
- CACNA1H | c.3066C>T p.G1022= | Splice Region (SNP) | VAF 12/29 reads (41%) | catalogued as rs757098120; ClinVar: uncertain significance; called by muse, varscan2
- CACNA1I | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs768172049, COSV60816271; called by muse, varscan2
- CACNA1S | c.2099C>T p.T700M | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs147112322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1S | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs150218077; ClinVar: uncertain significance; called by muse, mutect2
- CACNA2D3 | c.1470C>T p.T490= | Splice Region (SNP) | VAF 20/39 reads (51%) | catalogued as rs775379312, COSV55516775; called by muse, mutect2, varscan2
- CACNA2D3 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs758120700, COSV55518521; called by muse, mutect2, varscan2
- CACNA2D3 | c.2528G>A p.G843D | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs867611273, COSV99870815; called by muse, mutect2, varscan2
- CACNA2D4 | c.2939G>A p.S980N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1400684592; called by muse, mutect2, varscan2
- CACNB1 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as rs1009806701, COSV100703641; called by muse, varscan2
- CACNB1 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs772819208, COSV59998244; called by muse, mutect2, varscan2
- CACNB2 | c.1873C>T p.R625C (on ENST00000324631 / NM_201596.3; = p.R570C on NM_000724.4) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1060499847, CM109294, COSV56628183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG3 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766742794, COSV50067741, COSV50082256; called by muse, mutect2, varscan2
- CACTIN | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as rs890738741; called by muse, varscan2
- CAD | c.2308C>T p.R770C | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1286557374, COSV53031022; called by muse, varscan2
- CADM4 | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.771); catalogued as COSV99731365; called by muse, mutect2, varscan2
- CADPS2 | c.3101C>T p.A1034V | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57352096, COSV57381135; called by muse, mutect2, varscan2
- CALCOCO2 | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.794); catalogued as rs781069382, COSV99363979; called by muse, mutect2, varscan2
- CALCR | c.1214C>T p.T405I (on ENST00000649521 / NM_001164737.2; = p.T389I on NM_001742.4) | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.05); catalogued as rs1209232400; called by muse, mutect2, varscan2
- CALD1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs142583902; called by muse, mutect2, varscan2
- CALHM5 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.847); catalogued as rs571775020, COSV62068805; called by muse, mutect2, varscan2
- CALN1 | c.22G>A p.A8T (on ENST00000329008 / NM_001017440.3; = p.A50T on NM_031468.4) | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs767526121, COSV61141568; called by muse, mutect2, varscan2
- CALU | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as rs774816656; called by muse, mutect2, varscan2
- CAMK1D | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as rs1322015233, COSV101123651; called by muse, mutect2, varscan2
- CAMK2A | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs761424198; called by muse, varscan2
- CAMK2B | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs776330459; called by muse, varscan2
- CAMK2D | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); catalogued as rs1318349233, CM137612; called by muse, mutect2, varscan2
- CANT1 | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.201); catalogued as COSV100185254; called by muse, mutect2, varscan2
- CANX | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as rs1339766611, COSV56006398; called by muse, mutect2, varscan2
- CAPN10 | c.1861G>A p.G621S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99550583; called by muse, mutect2, varscan2
- CAPN2 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs781468603, COSV54339190; called by muse, mutect2, varscan2
- CAPRIN2 | c.2863A>G p.T955A | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776471356; called by muse, mutect2, varscan2
- CARD11 | c.3137C>T p.A1046V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as rs377327574, COSV67800574; called by muse, varscan2
- CARD11 | c.3098C>T p.A1033V | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs770667388, COSV101210957, COSV67797644; called by muse, varscan2
- CARD14 | c.2101G>A p.E701K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs984278499, COSV100712576; called by muse, mutect2, varscan2
- CARMIL3 | c.2404C>T p.R802C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs771963322; called by muse, varscan2
- CASC3 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); catalogued as rs764903865, COSV52866345, COSV52868738; called by muse, mutect2, varscan2
- CASKIN2 | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as rs149947368; called by muse, varscan2
- CASP8 | c.1294C>T p.R432* (on ENST00000432109 / NM_033355.3; = p.R449* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as rs931648756, COSV51845077; called by muse, mutect2, varscan2
- CASP8AP2 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs1219121591; called by muse, mutect2, varscan2
- CASQ2 | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs758082383, COSV54773743; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASS4 | c.2185G>A p.V729M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as COSV64387751; called by muse, mutect2, varscan2
- CATSPER3 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs747946239; called by muse, mutect2, varscan2
- CATSPER4 | c.913G>A p.V305M | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750275512; called by muse, varscan2
- CATSPER4 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.746); catalogued as rs758328338; called by muse, varscan2
- CATSPERB | c.2652T>G p.N884K | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV56422408; called by muse, mutect2, varscan2
- CAVIN1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV63811705; called by muse, mutect2, varscan2
- CBLC | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1321205852, COSV54321930; called by muse, mutect2, varscan2
- CBLC | c.913G>A p.G305S | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs61755281; called by muse, mutect2, varscan2
- CBLL2 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.415); catalogued as COSV60368773; called by muse, mutect2, varscan2
- CBR3 | c.343T>G p.F115V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as rs774897801; called by muse, varscan2
- CBX1 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV99848117; called by muse, mutect2, varscan2
- CC2D1B | c.1845G>T p.K615N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.418); catalogued as COSV52561663; called by muse, mutect2, varscan2
- CC2D1B | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1181517830; called by muse, mutect2
- CCDC102B | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60138080; called by muse, mutect2, varscan2
- CCDC102B | c.1492G>T p.E498* | Nonsense Mutation (SNP) | VAF 21/34 reads (62%) | catalogued as COSV100102014, COSV60135503, COSV60137000; called by muse, mutect2, varscan2
- CCDC103 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764426959, COSV99493375; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC110 | c.2305C>T p.R769* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as rs199552759, COSV56873047; called by muse, mutect2, varscan2
- CCDC113 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs144908344; called by muse, mutect2, varscan2
- CCDC113 | c.862dup p.I288Nfs*2 | Frame Shift Ins (INS) | VAF 12/46 reads (26%) | catalogued as rs747423196; called by mutect2, pindel, varscan2
- CCDC127 | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs781615165; called by muse, mutect2, varscan2
- CCDC127 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs983986680, COSV57256768; called by muse, mutect2, varscan2
- CCDC158 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.703); catalogued as rs561723655; called by muse, mutect2, varscan2
- CCDC18 | c.1582C>T p.R528C (on ENST00000343253 / NM_001306076.1; = p.R529C on NM_206886.4) | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1182833944; called by muse, mutect2, varscan2
- CCDC180 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV63829621; called by muse, mutect2, varscan2
- CCDC180 | c.1712C>T p.A571V | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1394679068; called by muse, mutect2, varscan2
- CCDC185 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs780602669; called by muse, varscan2
- CCDC190 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as rs745760397; called by muse, mutect2, varscan2
- CCDC191 | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as rs138387426, COSV55673669; called by muse, varscan2
- CCDC22 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs1480887668, COSV59907050; called by muse, mutect2, varscan2
- CCDC22 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.879); catalogued as rs782683625; called by muse, mutect2, varscan2
- CCDC34 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs1470770654; called by muse, mutect2, varscan2
- CCDC40 | c.2309C>T p.A770V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749795585, COSV100884351; ClinVar: uncertain significance; called by muse, varscan2
- CCDC47 | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs1403278665; called by muse, mutect2, varscan2
- CCDC50 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.446); catalogued as rs372340168; called by muse, mutect2, varscan2
- CCDC66 | c.1289A>G p.D430G (on ENST00000394672 / NM_001353147.1; = p.D396G on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs770887123; called by muse, mutect2, varscan2
- CCDC69 | c.616-1G>T p.X206_splice | Splice Site (SNP) | VAF 19/36 reads (53%) | catalogued as COSV62600456; called by muse, mutect2, varscan2
- CCDC73 | c.1648dup p.I550Nfs*21 | Frame Shift Ins (INS) | VAF 37/122 reads (30%) | catalogued as rs761354865; called by mutect2, pindel, varscan2
- CCDC74A | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781396415, COSV54609605; called by muse, varscan2
- CCDC78 | c.1307C>T p.T436M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.133); catalogued as rs775569629; ClinVar: uncertain significance; called by muse, varscan2
- CCDC81 | c.1466C>T p.A489V (on ENST00000445632 / NM_001156474.2; = p.A399V on NM_021827.4) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs375368484; called by muse, mutect2
- CCDC81 | c.1885C>T p.R629C (on ENST00000445632 / NM_001156474.2; = p.R539C on NM_021827.4) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs756085576, COSV53578732; called by muse, mutect2, varscan2
- CCDC83 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs775185124; called by muse, mutect2, varscan2
- CCDC89 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs775520786, COSV57034441; called by muse, mutect2, varscan2
12,789 further variants in this file (9,377 protein-altering or splice-affecting, 3,111 silent, 301 other) are not listed here.
